FM case AD1476 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Nevi and Melanomas.
https://portal.gdc.cancer.gov/cases/2d82b510-e192-48d0-9e6d-aef2d6538cf7

Female, 64.0 years: Melanoma, NOS (ICD-O-3 8720/3); specimen biopsied or resected from the rectum. Tumor nuclei on the sequenced sample's slide: 50% (pathologist estimate recorded by GDC). Sample type: Tumor.
